Somatic mutation profile of tumor specimen TCGA-AP-A0LD-01A (aliquot TCGA-AP-A0LD-01A-11W-A062-09) from TCGA case TCGA-AP-A0LD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 63.6 years (23,216 days).
Specimen TCGA-AP-A0LD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b747602-b1a4-460c-8245-c0be90ae5482.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LD-10A (Blood Derived Normal), aliquot TCGA-AP-A0LD-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed6d1503-75a7-4561-82df-b0ba409413b8

The open-access MAF lists 597 somatic variants for this specimen: 457 protein-altering or splice-affecting, 133 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 314, Silent 133, Frame Shift Del 100, Nonsense Mutation 20, Frame Shift Ins 12, Splice Site 5, RNA 3, Nonstop Mutation 2, Splice Region 2, 5'Flank 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 62/152 reads (41%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FOXRED1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758966293, COSV55007829; ClinVar: likely pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 76/163 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 85/169 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 140/244 reads (57%) | catalogued as rs1554893808, CM110124, COSV64297332, COSV64308587, COSV64311451; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 86/204 reads (42%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA10 | c.3794T>C p.L1265S | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV52226445; called by muse, mutect2, varscan2
- ABCB8 | c.1055G>A p.R352Q (on ENST00000297504 / NM_001282291.2; = p.R335Q on NM_007188.5) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.063); catalogued as rs749467318, COSV52505052; called by muse, mutect2, varscan2
- ACOT11 | c.839A>G p.D280G | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59350367; called by muse, mutect2, varscan2
- ACSL3 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs764207762, COSV62483653; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 105/220 reads (48%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS17 | c.1970C>A p.P657H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51487026; called by muse, mutect2, varscan2
- ADCK1 | c.1136G>A p.C379Y | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53079475, COSV53083264; called by muse, mutect2, varscan2
- ADCY6 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs200747404; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- ADNP2 | c.2779A>G p.T927A | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51540847; called by muse, mutect2, varscan2
- ADSL | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs370851726, CM068484; called by muse, mutect2, varscan2
- AGK | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV62595269; called by muse, mutect2, varscan2
- AHCTF1 | c.3779G>A p.R1260Q (on ENST00000366508; = p.R1234Q on NM_015446.5) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs372858806; called by muse, mutect2, varscan2
- AKAP11 | c.4079G>A p.S1360N | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV50298870; called by muse, mutect2, varscan2
- AKAP8L | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775614362, COSV68472785; called by muse, mutect2, varscan2
- AKAP9 | c.4996C>A p.L1666M | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV62352326; called by muse, mutect2, varscan2
- AKNA | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs906817866, COSV56313829, COSV56314478; called by muse, mutect2, varscan2
- ALDH3B2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62428536; called by muse, mutect2, varscan2
- ALG14 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV64635385; called by muse, mutect2, varscan2
- ALK | c.4672G>C p.E1558Q | Missense Mutation (SNP) | VAF 141/367 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.747); catalogued as COSV66579663; called by muse, mutect2, varscan2
- AMER1 | c.1895A>T p.E632V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV57664112; called by muse, mutect2, varscan2
- ANKS4B | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747762926, COSV61139730; called by muse, mutect2, varscan2
- ANLN | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 58/132 reads (44%) | catalogued as rs200989750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP2A2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59962298; called by muse, mutect2, varscan2
- APC | c.6747del p.G2250Afs*29 | Frame Shift Del (DEL) | VAF 96/252 reads (38%) | catalogued as rs773874693; called by mutect2, pindel, varscan2
- APOL2 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV50772497; called by muse, mutect2, varscan2
- ARF6 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as COSV53597984; called by muse, mutect2, varscan2
- ARFIP1 | c.844C>T p.R282C (on ENST00000353617 / NM_001287432.1; = p.R250C on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368185805; called by muse, mutect2, varscan2
- ARHGEF15 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.994); catalogued as COSV62725845; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 56/200 reads (28%) | catalogued as COSV61389445; called by pindel, varscan2
- ARID5B | c.3026C>G p.A1009G | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV54415348; called by muse, mutect2, varscan2
- ARNTL | c.1646C>A p.P549H (on ENST00000403290 / NM_001297719.2; = p.P548H on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV53400322; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | catalogued as rs759638000; called by mutect2, varscan2
- B3GNT7 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV55007091; called by muse, mutect2, varscan2
- BAG5 | c.1229A>G p.D410G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54571995; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 53/98 reads (54%) | catalogued as rs768244116; called by mutect2, varscan2
- BIN1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs766894632, COSV52120226; called by muse, mutect2, varscan2
- BMP7 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 95/189 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.312); catalogued as rs764633584, COSV67780354; called by muse, mutect2, varscan2
- BTAF1 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56436715; called by muse, mutect2, varscan2
- BTN3A1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV50025079; called by muse, mutect2, varscan2
- BTNL3 | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV61565286; called by muse, varscan2
- BUD13 | c.811T>C p.S271P | Missense Mutation (SNP) | VAF 123/320 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV52769638; called by muse, mutect2, varscan2
- C10orf99 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs762789784, COSV64532068; called by muse, mutect2, varscan2
- C17orf98 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.319); catalogued as rs866750911; called by muse, mutect2, varscan2
- CACNA1D | c.4135G>T p.D1379Y (on ENST00000350061 / NM_001128840.3; = p.D1399Y on NM_000720.4) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55456365; called by muse, mutect2, varscan2
- CACNA1G | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs562004080, COSV61732564; called by muse, mutect2, varscan2
- CALML3 | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV59449629, COSV59449845; called by muse, mutect2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 64/257 reads (25%) | catalogued as rs1375954479; called by mutect2, varscan2
- CAPN10 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774894214, COSV54377749; called by muse, mutect2
- CARMIL3 | c.1963-2A>G p.X655_splice | Splice Site (SNP) | VAF 12/25 reads (48%) | catalogued as rs942313478, COSV57727504; called by muse, mutect2, varscan2
- CCDC106 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs373493546; called by muse, mutect2, varscan2
- CCDC3 | c.383A>G p.E128G | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66560732; called by muse, mutect2, varscan2
- CCDC83 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs553174518, COSV54700993, COSV54703567; called by muse, mutect2, varscan2
- CCDC9B | c.609del p.T204Rfs*44 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | catalogued as rs772754432; called by mutect2, pindel, varscan2
- CCNE2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV57376845; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 69/158 reads (44%) | catalogued as rs773911500; called by mutect2, varscan2
- CDH13 | c.1328A>G p.K443R | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.113); catalogued as COSV51846026; called by muse, mutect2, varscan2
- CDH4 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as rs1201669774, COSV64648959; called by muse, mutect2, varscan2
- CDH9 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 72/163 reads (44%) | catalogued as rs779923057, COSV50275360, COSV50343795; called by muse, mutect2, varscan2
- CDNF | c.466del p.E156Rfs*13 | Frame Shift Del (DEL) | VAF 53/224 reads (24%) | catalogued as COSV101012365; called by mutect2, pindel, varscan2
- CEACAM5 | c.1537G>A p.V513M | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); catalogued as rs138295038, COSV99703874; called by muse, mutect2, varscan2
- CENPL | c.773C>A p.P258Q | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61892517; called by muse, mutect2, varscan2
- CEP350 | c.5527A>G p.M1843V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV62606374; called by muse, mutect2, varscan2
- CES1 | c.581A>G p.Q194R | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62088693; called by muse, mutect2, varscan2
- CFH | c.3263A>G p.E1088G | Missense Mutation (SNP) | VAF 111/581 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV66410893; called by muse, mutect2, varscan2
- CHST5 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs759608563, COSV60337345, COSV60340515; called by muse, mutect2, varscan2
- CLK2 | c.1319G>A p.R440Q (on ENST00000368361 / NM_001294339.2; = p.R439Q on NM_003993.4) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV56946539; called by muse, mutect2, varscan2
- CLK2 | c.785A>G p.Y262C (on ENST00000368361 / NM_001294339.2; = p.Y261C on NM_003993.4) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56946544; called by muse, mutect2, varscan2
- CLVS1 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.149); catalogued as rs146292772, COSV100370258; called by muse, mutect2, varscan2
- CNGA2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 137/293 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754448035, COSV61704327; called by muse, mutect2, varscan2
- CNTN2 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1385031562, COSV59351536; called by muse, mutect2, varscan2
- CNTNAP3 | c.3731_3732del p.S1244Cfs*35 | Frame Shift Del (DEL) | VAF 34/178 reads (19%) | catalogued as rs1295672827; called by pindel, varscan2
- COBL | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54343450, COSV54351743; called by muse, mutect2, varscan2
- COL12A1 | c.2126T>C p.F709S | Missense Mutation (SNP) | VAF 103/274 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.053); catalogued as COSV59401349; called by muse, mutect2, varscan2
- COL1A2 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51954486, COSV51962001; called by muse, mutect2, varscan2
- COQ5 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs529965711, COSV56019688; called by muse, mutect2, varscan2
- CPA1 | c.1212G>A p.W404* | Nonsense Mutation (SNP) | VAF 111/274 reads (41%) | catalogued as COSV50572237; called by muse, mutect2, varscan2
- CPEB4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 111/251 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV54174220; called by muse, mutect2, varscan2
- CPEB4 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54174235; called by muse, mutect2, varscan2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | catalogued as COSV51715473; called by mutect2, pindel, varscan2
- CRTAC1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs200767311, COSV53996883; called by muse, mutect2, varscan2
- CS | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60834094; called by muse, mutect2
- CSPG5 | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as COSV53132262; called by muse, mutect2, varscan2
- CYLC1 | c.1892C>A p.P631H | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61412500; called by muse, mutect2, varscan2
- CYP1A1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs371913955; called by muse, mutect2, varscan2
- DARS2 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs755142844, COSV53407941; called by muse, mutect2, varscan2
- DCAF1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.97); catalogued as COSV60044915; called by muse, mutect2, varscan2
- DCAF4L1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60787947; called by muse, mutect2, varscan2
- DCC | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 133/322 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200830938; called by muse, mutect2, varscan2
- DCTD | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63867097; called by muse, mutect2, varscan2
- DDI2 | c.709T>C p.Y237H | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60780495; called by muse, mutect2, varscan2
- DDIT4 | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV56577871; called by muse, mutect2, varscan2
- DDX3X | c.325C>T p.R109C (on ENST00000399959; = p.R110C on NM_001356.5) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1444942370, COSV101302352, COSV67863950; called by muse, mutect2, varscan2
- DECR2 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.66); catalogued as rs1281309069, COSV54793062; called by muse, mutect2, varscan2
- DENND2B | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs377206146; called by muse, mutect2, varscan2
- DEPDC1 | c.2354A>G p.E785G (on ENST00000456315 / NM_001114120.3; = p.E501G on NM_017779.6) | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63958647; called by muse, mutect2, varscan2
- DLX4 | c.22del p.L8Sfs*20 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as COSV53592981; called by mutect2, varscan2
- DMBT1 | c.1769G>A p.G590D | Missense Mutation (SNP) | VAF 98/168 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1340820817, COSV100353301, COSV57552174; called by muse, mutect2, varscan2
- DMBX1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63602332; called by muse, mutect2, varscan2
- DMXL1 | c.3947A>G p.H1316R | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.079); catalogued as COSV60716916; called by muse, mutect2, varscan2
- DNAH11 | c.12145C>A p.P4049T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60967105; called by muse, mutect2, varscan2
- DNAH2 | c.5431G>A p.E1811K | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752893784, COSV66722707; called by muse, mutect2, varscan2
- DOCK5 | c.4850C>T p.P1617L | Missense Mutation (SNP) | VAF 219/400 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs139076084; called by muse, mutect2, varscan2
- DSC1 | c.1742T>C p.V581A | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV57148587; called by muse, mutect2, varscan2
- DST | c.21328C>T p.R7110W (on ENST00000361203 / NM_001374722.1; = p.R4807W on NM_015548.5) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754663787, COSV55010401; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DUSP10 | c.1349A>C p.N450T | Missense Mutation (SNP) | VAF 90/328 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60458866; called by muse, mutect2, varscan2
- EDRF1 | c.3395C>T p.P1132L (on ENST00000356792 / NM_001202438.2; = p.P1098L on NM_015608.2) | Missense Mutation (SNP) | VAF 76/318 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs777112221, COSV61765185; called by muse, mutect2, varscan2
- EFEMP2 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57260818, COSV57261686; called by muse, mutect2, varscan2
- EFR3A | c.1492G>T p.G498W | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV54459923, COSV99603758; called by muse, mutect2, varscan2
- EIF3A | c.4027C>T p.R1343* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as rs763416725, COSV60775500; called by muse, mutect2, varscan2
- EIF3E | c.462del p.F154Lfs*13 | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | catalogued as rs1554600455; called by pindel, varscan2
- EML5 | c.5690T>C p.V1897A (on ENST00000380664; = p.V1905A on NM_183387.3) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs750889645, COSV51771615; called by muse, mutect2, varscan2
- EPRS1 | c.3997C>T p.R1333* | Nonsense Mutation (SNP) | VAF 78/247 reads (32%) | catalogued as COSV65098536; called by muse, mutect2, varscan2
- ERBB4 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.605); catalogued as rs755026855, COSV53501697; called by muse, mutect2, varscan2
- ERI2 | c.304-2A>G p.X102_splice | Splice Site (SNP) | VAF 50/136 reads (37%) | catalogued as COSV55502720; called by muse, mutect2, varscan2
- ERP44 | c.907A>T p.K303* | Nonsense Mutation (SNP) | VAF 52/115 reads (45%) | catalogued as COSV52433394; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 96/119 reads (81%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRRB | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs1316154782, COSV55064122; called by muse, mutect2, varscan2
- EVC | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 128/325 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs201583621, COSV53833359; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EWSR1 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1331151554, COSV58425698; called by muse, mutect2, varscan2
- EXOSC7 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV55557258; called by muse, mutect2, varscan2
- FAM13B | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV50369390; called by muse, mutect2, varscan2
- FAM214A | c.852A>C p.K284N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV55925812; called by muse, mutect2, varscan2
- FAM83C | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as rs376562401; called by muse, mutect2, varscan2
- FASN | c.5560G>T p.V1854L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV60757978; called by muse, mutect2, varscan2
- FBN2 | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs370804151, COSV52543595; called by muse, mutect2, varscan2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 13/27 reads (48%) | catalogued as COSV54456788; called by mutect2, varscan2
- FBXO10 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV52834292; called by muse, mutect2
- FER1L6 | c.1949dup p.P651Afs*11 | Frame Shift Ins (INS) | VAF 124/244 reads (51%) | catalogued as rs765775004; called by mutect2, varscan2
- FLNB | c.5699C>A p.P1900H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55886869; called by muse, mutect2, varscan2
- FRAS1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs200764508, COSV53628624; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMPD1 | c.3857G>T p.S1286I | Missense Mutation (SNP) | VAF 75/132 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV66701436; called by muse, mutect2, varscan2
- FRMPD3 | c.4238del p.G1413Afs*12 | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | catalogued as COSV52189566; called by mutect2, pindel, varscan2
- GANC | c.903G>T p.E301D | Missense Mutation (SNP) | VAF 45/105 reads (43%) | PolyPhen benign (0.003); catalogued as COSV58810418; called by muse, mutect2, varscan2
- GBA | c.203del p.P68Rfs*23 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | catalogued as CD941682; called by mutect2, pindel, varscan2
- GCN1 | c.7180G>A p.A2394T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs919946892, COSV56111227; called by muse, mutect2, varscan2
- GDPD2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs370359972, COSV65533662; called by muse, mutect2, varscan2
- GET1 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61555130; called by muse, mutect2, varscan2
- GIGYF2 | c.1171G>C p.A391P | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV65251610; called by muse, mutect2, varscan2
- GKN2 | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV61031620; called by muse, mutect2
- GPR137B | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV63991314; called by muse, mutect2, varscan2
- GRM5 | c.599G>T p.R200M | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV59615990; called by muse, mutect2, varscan2
- GRM8 | c.2356A>G p.T786A | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV58819055, COSV58846868; called by muse, mutect2, varscan2
- GRPEL1 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs757011343, COSV53827668; called by muse, mutect2, varscan2
- GTF3C1 | c.3785G>A p.R1262H | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756682862, COSV62242947; called by muse, mutect2, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 46/115 reads (40%) | catalogued as rs750792116; called by mutect2, varscan2
- HAL | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54117041; called by muse, mutect2, varscan2
- HAS1 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs370795750; called by muse, mutect2, varscan2
- HDAC4 | c.2874G>T p.K958N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV61870773; called by muse, mutect2, varscan2
- HDAC6 | c.1751G>A p.G584D | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61929849; called by muse, mutect2, varscan2
- HEATR1 | c.3970A>G p.M1324V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63982164; called by muse, mutect2, varscan2
- HEATR5B | c.4274C>A p.A1425D | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51855846; called by muse, mutect2, varscan2
- HELT | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV58820279; called by muse, mutect2, varscan2
- HERC2 | c.2239G>A p.V747M | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as rs1402447763, COSV55320420; called by muse, mutect2, varscan2
- HIPK2 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.891); catalogued as COSV61230507; called by muse, mutect2
- HK2 | c.2701del p.A901Rfs*74 | Frame Shift Del (DEL) | VAF 65/210 reads (31%) | catalogued as rs771887254; called by mutect2, pindel, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs777829525; called by mutect2, varscan2
- HTT | c.8741G>T p.R2914L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as rs752690276, COSV61863794, COSV61865635; called by muse, mutect2, varscan2
- IFT88 | c.1537G>A p.A513T (on ENST00000319980 / NM_001318493.2; = p.A504T on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.12); catalogued as rs551160953, COSV60674400; called by muse, mutect2, varscan2
- IGF1R | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV51284745; called by muse, mutect2, varscan2
- INVS | c.2659C>T p.Q887* | Nonsense Mutation (SNP) | VAF 30/93 reads (32%) | catalogued as COSV52445976, COSV52451793; called by muse, mutect2, varscan2
- IQCD | c.1195C>T p.R399C (on ENST00000416617 / NM_001330452.2; = p.R297C on NM_138451.3) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.634); catalogued as rs372339091; called by muse, mutect2, varscan2
- JADE2 | c.831C>G p.S277R | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV50922726; called by muse, mutect2, varscan2
- KANK4 | c.2986T>C p.*996Qext*22 | Nonstop Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58093430; called by muse, mutect2, varscan2
- KANSL1 | c.1601T>C p.L534P | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV52271356; called by muse, mutect2, varscan2
- KCNA7 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.275); catalogued as rs531366512, COSV55503984; called by muse, mutect2, varscan2
- KCNT2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54093636; called by muse, mutect2, varscan2
- KCTD18 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as rs774750730, COSV100728976, COSV63344811; called by muse, mutect2, varscan2
- KDM4B | c.104T>A p.I35K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV50236585; called by muse, mutect2, varscan2
- KHDC3L | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV64859390; called by muse, mutect2
- KIAA0586 | c.3137C>T p.T1046M (on ENST00000619416 / NM_001244190.2; = p.T985M on NM_014749.5) | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564215930, COSV54179142; called by muse, mutect2, varscan2
- KIAA0895L | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs202158207; called by muse, mutect2, varscan2
- KIAA0895L | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs955997882, COSV51783678; called by muse, mutect2, varscan2
- KIF21A | c.3304G>T p.G1102C (on ENST00000361418 / NM_001378440.1; = p.G1089C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62774846; called by muse, mutect2, varscan2
- KIF5A | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs773924317, COSV54056861; called by muse, mutect2, varscan2
- KIF9 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs114859156; called by muse, mutect2, varscan2
- KLHL28 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.467); catalogued as rs546980465, COSV100753253, COSV61888840; called by muse, mutect2, varscan2
- KLHL3 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59051221; called by muse, mutect2, varscan2
- KMT2C | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV51470165; called by muse, mutect2, varscan2
- KMT2D | c.4160G>C p.G1387A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM156342, COSV56464267, COSV56482157, COSV56500236; called by muse, mutect2, varscan2
- KRT19 | c.1066A>G p.S356G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54180747; called by muse, mutect2, varscan2
- KRT4 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs1405060384, COSV53408725, COSV99542972; called by muse, mutect2, varscan2
- KRT8 | c.644A>T p.E215V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV53178328; called by muse, mutect2, varscan2
- KRT83 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV53341333; called by muse, mutect2, varscan2
- KRTAP10-4 | c.373T>A p.C125S | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV59970862; called by muse, varscan2
- LAMA3 | c.2144A>G p.Q715R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV58073811; called by muse, mutect2, varscan2
- LAMB2 | c.4031A>G p.E1344G | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59735683; called by muse, mutect2, varscan2
- LARGE1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs574367881, COSV61666525; called by muse, mutect2, varscan2
- LCT | c.3440T>C p.L1147P | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51553756; called by muse, mutect2, varscan2
- LGI3 | c.423C>T p.L141= | Splice Region (SNP) | VAF 20/38 reads (53%) | catalogued as COSV60443845; called by muse, mutect2
- LIG3 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as rs1567694313, COSV52009311; called by muse, mutect2, varscan2
- LRRC8A | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1321154896, COSV52185559, COSV52187805; called by muse, mutect2, varscan2
- LUC7L | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53459550; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV65443032; called by muse, mutect2, varscan2
- LY9 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 90/347 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as rs376163756; called by muse, mutect2, varscan2
- MACF1 | c.13249G>T p.G4417* (on ENST00000372915; = p.G2350* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as COSV57132497; called by muse, mutect2, varscan2
- MACF1 | c.18803del p.N6268Mfs*32 (on ENST00000372915; = p.N4313Mfs*32 on NM_012090.5) | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as rs748961150; called by mutect2, pindel, varscan2
- MAGEC1 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 435/963 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.134); catalogued as COSV53577223; called by muse, mutect2, varscan2
- MAN2A2 | c.2170C>A p.L724M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as COSV64639086; called by muse, mutect2, varscan2
- MAP3K1 | c.2941C>G p.P981A | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.079); catalogued as COSV68125448; called by muse, mutect2, varscan2
- MARF1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 94/221 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV60026255; called by muse, mutect2, varscan2
- MCF2L | c.2209C>A p.L737M (on ENST00000375608; = p.L705M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56179617; called by muse, mutect2, varscan2
- MED12L | c.2828G>T p.R943I | Missense Mutation (SNP) | VAF 146/306 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV56387664; called by muse, mutect2, varscan2
- MEGF10 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370717384, COSV57253128; called by muse, mutect2, varscan2
- MGA | c.2862del p.F954Lfs*40 | Frame Shift Del (DEL) | VAF 69/221 reads (31%) | catalogued as COSV54964891; called by mutect2, pindel, varscan2
- MINDY2 | c.840+2T>C p.X280_splice | Splice Site (SNP) | VAF 16/57 reads (28%) | catalogued as COSV57507734; called by muse, mutect2, varscan2
- MINDY4 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs756260993, COSV54676245; called by muse, mutect2, varscan2
- MKI67 | c.5569del p.I1857Yfs*30 | Frame Shift Del (DEL) | VAF 162/542 reads (30%) | catalogued as rs866533107; called by mutect2, varscan2
- MLIP | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1203730904, COSV51433599; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2759C>A p.T920N | Missense Mutation (SNP) | VAF 101/243 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as COSV56622030; called by muse, mutect2, varscan2
- MPO | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.054); catalogued as rs1016099901, COSV56562015; called by muse, mutect2, varscan2
- MPRIP | c.3048C>G p.S1016= | Splice Region (SNP) | VAF 31/88 reads (35%) | catalogued as COSV57928812; called by muse, mutect2, varscan2
- MROH8 | c.1482dup p.N495Kfs*4 | Frame Shift Ins (INS) | VAF 13/27 reads (48%) | catalogued as rs1483444302; called by mutect2, pindel, varscan2
- MS4A6A | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as COSV60620613; called by muse, mutect2, varscan2
- MTX1 | c.682T>C p.Y228H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201017167, COSV57427405; called by muse, mutect2, varscan2
- MUC17 | c.1448T>C p.V483A | Missense Mutation (SNP) | VAF 291/697 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV60296063; called by mutect2, varscan2
- MX1 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as COSV55820112; called by muse, mutect2, varscan2
- MYH8 | c.1319T>C p.L440P | Missense Mutation (SNP) | VAF 193/448 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.854); catalogued as rs1329312571, COSV67965845; called by muse, mutect2, varscan2
- MYPN | c.2037C>G p.N679K | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV62736095; called by muse, mutect2, varscan2
- NEK5 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62881093; called by muse, mutect2, varscan2
- NELFE | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 55/121 reads (45%) | catalogued as rs1490077337, COSV64811058, COSV64812477; called by muse, mutect2, varscan2
- NELL2 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100421310, COSV61580273; called by muse, mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 51/147 reads (35%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NLRP1 | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as rs1171910404, COSV52571974; called by muse, mutect2, varscan2
- NLRP3 | c.1736T>C p.F579S | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs752389053, COSV60228503; called by muse, mutect2, varscan2
- NOA1 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51737942; called by muse, mutect2, varscan2
- NODAL | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.552); catalogued as COSV54662028; called by muse, mutect2, varscan2
- NOMO2 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 104/289 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs745560186, COSV57917348; called by muse, mutect2, varscan2
- NOP56 | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV61390811; called by muse, mutect2, varscan2
- NR2E1 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV64562404; called by muse, mutect2, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 52/175 reads (30%) | catalogued as rs1167519601; called by mutect2, varscan2
- NUDT6 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV58646990; called by muse, mutect2
- NUP107 | c.2293A>G p.K765E | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV57496276; called by muse, mutect2, varscan2
- NXF5 | n.840+2T>C | Splice Site (SNP) | VAF 242/596 reads (41%) | catalogued as rs1371866381, COSV53792253, COSV53793319; called by muse, mutect2, varscan2
- OAT | c.1250C>A p.P417Q | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM920530, COSV64347933; called by muse, mutect2, varscan2
- OBSCN | c.14380C>T p.R4794C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs537345164, COSV52783497, COSV52800099; called by muse, mutect2, varscan2
- OPHN1 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555988278, COSV62784569; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10G4 | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 114/297 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.529); catalogued as COSV57977273; called by muse, mutect2, varscan2
- OR10H5 | c.859A>G p.S287G | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58278751; called by muse, varscan2
- OR10J3 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV59955100; called by muse, mutect2, varscan2
- OR1B1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59172065; called by muse, mutect2, varscan2
- OR2G2 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 89/368 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60741374, COSV60742217; called by muse, mutect2, varscan2
- OR51B6 | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV66512927; called by muse, mutect2, varscan2
- OR52N5 | c.379A>G p.M127V | Missense Mutation (SNP) | VAF 115/258 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs768968411, COSV57699174; called by muse, mutect2, varscan2
- OR5H6 | c.751C>T p.R251* (on ENST00000642105; = p.R235* on NM_001005479.2) | Nonsense Mutation (SNP) | VAF 54/136 reads (40%) | catalogued as rs201434146, COSV67351164; called by muse, mutect2, varscan2
- OR5T2 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 153/379 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57590189; called by muse, mutect2, varscan2
- OSBP | c.1999C>T p.R667* | Nonsense Mutation (SNP) | VAF 69/253 reads (27%) | catalogued as COSV55664224; called by muse, mutect2, varscan2
- OSER1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV54853754; called by muse, mutect2, varscan2
- P3H2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537288155, COSV60024619; called by muse, mutect2, varscan2
- PANK3 | c.1066T>A p.Y356N | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53324255; called by muse, mutect2, varscan2
- PANK4 | c.1881A>G p.I627M | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV65867336; called by muse, mutect2, varscan2
- PAPOLB | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 144/347 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1562454376, COSV68201462; called by muse, mutect2, varscan2
- PAPPA | c.2570C>T p.T857M | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374066435; called by muse, mutect2, varscan2
- PARP8 | c.1072A>C p.K358Q | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV55863314; called by muse, mutect2, varscan2
- PDCD11 | c.1570A>C p.T524P | Missense Mutation (SNP) | VAF 75/280 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63934599, COSV63934690; called by muse, mutect2, varscan2
- PDE3B | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs761085973, COSV56381786; called by muse, mutect2, varscan2
- PGM1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs747394265, COSV64301051; called by muse, mutect2, varscan2
- PHF8 | c.917G>A p.R306H (on ENST00000357988 / NM_001184896.1; = p.R270H on NM_015107.3) | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV57684733; called by muse, mutect2, varscan2
- PHGDH | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs774423823, COSV65571657; called by muse, mutect2, varscan2
- PIAS3 | c.1766del p.P589Lfs*15 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | catalogued as COSV57906572; called by mutect2, pindel, varscan2
- PLCE1 | c.4583C>A p.P1528H | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53361108; called by muse, mutect2, varscan2
- PLCG1 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401614966, COSV54821137; called by muse, mutect2, varscan2
- PLEC | c.8585C>A p.T2862K (on ENST00000322810 / NM_201380.4; = p.T2752K on NM_000445.5) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs371900885, COSV59664085; called by muse, mutect2, varscan2
- PLTP | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV51943490; called by muse, mutect2, varscan2
- PPARG | c.1054G>A p.E352K (on ENST00000287820 / NM_015869.5; = p.E322K on NM_005037.7) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs530007199, CM123616, COSV55143767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R9A | c.1233T>A p.N411K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1308185291, COSV56901649; called by muse, mutect2, varscan2
- PPP1R9B | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs756899491, COSV57541129; called by muse, mutect2, varscan2
- PPP6R3 | c.1345G>A p.A449T (on ENST00000393800 / NM_001352375.2; = p.A398T on NM_018312.5) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV55731679; called by muse, mutect2, varscan2
- PRND | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.02); catalogued as rs1469322483, COSV59896969; called by muse, mutect2, varscan2
- PRPF6 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1569216086, COSV53874568; called by muse, mutect2, varscan2
- PRRC2A | c.5649del p.G1884Afs*12 | Frame Shift Del (DEL) | VAF 145/323 reads (45%) | catalogued as COSV52991311; called by mutect2, pindel, varscan2
- PTEN | c.710dup p.F238Vfs*5 | Frame Shift Ins (INS) | VAF 95/369 reads (26%) | catalogued as COSV64305428, COSV64309390; called by mutect2, pindel, varscan2
- PTK2B | c.2363G>A p.S788N | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV57761300; called by muse, mutect2, varscan2
- PTPN7 | c.806G>A p.R269H (on ENST00000495688; = p.R308H on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs777756781, COSV58311844; called by muse, mutect2
- PTPRK | c.4029A>C p.E1343D (on ENST00000368215 / NM_001291984.2; = p.E1344D on NM_002844.4) | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63902853; called by muse, mutect2, varscan2
- RAD51D | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV50102695; called by muse, mutect2, varscan2
- RAPGEF6 | c.1918del p.S640Vfs*59 | Frame Shift Del (DEL) | VAF 42/120 reads (35%) | catalogued as rs752725730; called by mutect2, varscan2
- RBAK | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62332016; called by muse, mutect2, varscan2
- RBM33 | c.2932G>A p.G978R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796719290, COSV56635074; called by muse, mutect2, varscan2
- RBSN | c.1613G>T p.R538L | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV53794463; called by muse, mutect2, varscan2
- RETSAT | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55527386, COSV55529673; called by muse, mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 37/94 reads (39%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RMC1 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV52573078; called by muse, mutect2, varscan2
- RNF213 | c.14879T>C p.I4960T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV60403528; called by muse, mutect2, varscan2
- ROS1 | c.2224C>A p.L742I | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63858507; called by muse, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 87/515 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs768368074, COSV64820491; called by muse, mutect2, varscan2
- RPS26 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.286); catalogued as COSV56269743; called by muse, mutect2
- RXRA | c.1235C>A p.P412Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.19); catalogued as COSV62684814; called by muse, mutect2, varscan2
- SAFB | c.2399dup p.Y801Lfs*4 | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | catalogued as rs747412640; called by mutect2, varscan2
- SALL2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs759194170, COSV58104682; called by muse, mutect2, varscan2
- SALL4 | c.1173T>G p.F391L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV53854337; called by muse, mutect2, varscan2
- SCGN | c.401T>A p.L134H | Missense Mutation (SNP) | VAF 131/338 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58546383; called by muse, mutect2, varscan2
- SDK2 | c.5042C>T p.A1681V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV66191510; called by muse, mutect2, varscan2
- SERPINE1 | c.978G>T p.Q326H | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV56170669; called by muse, mutect2, varscan2
- SF3B1 | c.3890G>A p.R1297H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1352116876, COSV59220777; called by muse, mutect2, varscan2
- SGK3 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 132/269 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV61895697; called by muse, mutect2, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 45/121 reads (37%) | catalogued as rs747473028; called by mutect2, varscan2
- SHROOM2 | c.4531C>T p.R1511W | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66608862; called by muse, mutect2, varscan2
- SHROOM3 | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1047856322, COSV56034616; called by muse, mutect2, varscan2
- SIGLEC12 | c.1432A>G p.T478A (on ENST00000291707 / NM_053003.4; = p.T360A on NM_033329.2) | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as rs1450949590, COSV52463248; called by muse, mutect2, varscan2
- SIK2 | c.2705A>G p.E902G | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV59254389; called by muse, mutect2, varscan2
- SLC16A5 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs761846500, COSV61676359; called by muse, mutect2, varscan2
- SLC18A3 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs200894047, COSV60328304; called by muse, mutect2, varscan2
- SMC6 | c.1228dup p.I410Nfs*40 | Frame Shift Ins (INS) | VAF 58/148 reads (39%) | catalogued as rs760667210; called by mutect2, varscan2
- SMPD3 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as COSV54713652; called by muse, mutect2, varscan2
- SOCS5 | c.1010G>T p.R337M | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV100125498, COSV60605700; called by muse, mutect2
- SORCS2 | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs370004831; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 85/193 reads (44%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPTA1 | c.4681C>A p.L1561M | Missense Mutation (SNP) | VAF 74/302 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV63756737; called by muse, mutect2
- STRN | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 130/329 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55745546; called by muse, mutect2, varscan2
- STT3A | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1565352801, COSV67065191; called by muse, mutect2, varscan2
- STXBP6 | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60595126; called by muse, mutect2, varscan2
- SUPT20HL2 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.082); catalogued as rs184929479; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs753462162; called by mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 72/168 reads (43%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNE1 | c.23258G>A p.R7753H (on ENST00000367255 / NM_182961.4; = p.R7682H on NM_033071.3) | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779568455, COSV55038859; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT14 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV55058979; called by muse, mutect2, varscan2
- TAF5L | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51084365; called by muse, mutect2, varscan2
- TAGAP | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV57852625; called by muse, mutect2, varscan2
- TARBP1 | c.3511C>T p.R1171* | Nonsense Mutation (SNP) | VAF 133/438 reads (30%) | catalogued as rs763820689, COSV50193270; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 60/76 reads (79%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBCK | c.1475C>T p.A492V (on ENST00000273980 / NM_001163436.4; = p.A429V on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as rs772296511, COSV56759037; called by muse, mutect2, varscan2
- TBX22 | c.472A>G p.S158G | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV64787039; called by muse, mutect2, varscan2
- TECTA | c.2414A>G p.K805R | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV50750807; called by muse, mutect2, varscan2
- TES | c.775A>T p.K259* | Nonsense Mutation (SNP) | VAF 9/255 reads (4%) | catalogued as COSV64043055; called by muse, mutect2
- TET1 | c.1675A>G p.T559A | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV65387062; called by muse, mutect2, varscan2
- TEX15 | c.3018dup p.A1007Sfs*3 (on ENST00000256246; = p.A1390Sfs*3 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 111/297 reads (37%) | catalogued as rs753315680; called by mutect2, varscan2
- TGFBR1 | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV66625943; called by muse, mutect2, varscan2
- THAP8 | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53078606; called by muse, mutect2, varscan2
- THEMIS | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 119/256 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64072673; called by muse, mutect2, varscan2
- THSD7A | c.3935G>A p.R1312Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs370952536, COSV69855496; called by muse, mutect2, varscan2
- TIMP1 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV54482762; called by muse, mutect2, varscan2
- TLE6 | c.1717T>C p.*573Rext*? (on ENST00000246112 / NM_001143986.2; = p.*450Rext*? on NM_024760.3) | Nonstop Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV53581632; called by muse, mutect2
- TLR6 | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs754352785, COSV67935502; called by muse, mutect2, varscan2
- TMBIM4 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs1157992566, COSV53969718; called by muse, mutect2, varscan2
- TMC5 | c.2493G>T p.Q831H (on ENST00000396229 / NM_001105248.1; = p.Q585H on NM_024780.5) | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV54906909; called by muse, mutect2, varscan2
- TMEM132E | c.2461G>A p.V821I (on ENST00000321639; = p.V911I on NM_001304438.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV58698978; called by muse, mutect2, varscan2
- TOP2A | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as rs1429745884, COSV70732442; called by muse, mutect2, varscan2
- TP63 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029852196, COSV53213668, COSV53216180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPR | c.5510A>G p.D1837G | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs1196268442, COSV66603173; called by muse, mutect2, varscan2
- TPRA1 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV56161407; called by muse, mutect2, varscan2
- TRAF4 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1191777934, COSV52219106; called by muse, mutect2, varscan2
- TRAIP | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs142854364; called by muse, mutect2, varscan2
- TRAPPC10 | c.2674G>A p.G892R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs751419431, COSV52379380; called by muse, mutect2, varscan2
- TRIM7 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV51247094; called by muse, mutect2, varscan2
- TRPM4 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as rs1019057830, COSV53265998; called by muse, mutect2, varscan2
- TSPOAP1 | c.4769C>A p.S1590Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.231); catalogued as COSV52113206; called by muse, mutect2, varscan2
- TSPYL2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as rs782435988, COSV60237223; called by muse, mutect2, varscan2
- TSPYL6 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57817438; called by muse, mutect2, varscan2
- TTC21B | c.3851A>G p.D1284G | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54632757; called by muse, mutect2, varscan2
- TTN | c.78628C>T p.P26210S (on ENST00000591111; = p.P18786S on NM_003319.4) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | PolyPhen probably damaging (0.996); catalogued as COSV60198067; called by muse, mutect2, varscan2
- TUBB2B | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV52534137; called by muse, mutect2, varscan2
- TUBB8 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 87/289 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as rs782110615, COSV59116909; called by muse, mutect2, varscan2
- UBA1 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60114183; called by muse, mutect2, varscan2
- UBAP2L | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55177066; called by muse, mutect2, varscan2
- UNC45A | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1014212696, COSV57746454; called by muse, mutect2, varscan2
- USP9X | c.82dup p.L28Pfs*10 | Frame Shift Ins (INS) | VAF 25/53 reads (47%) | catalogued as rs758083405; called by mutect2, varscan2
- UTRN | c.4378G>A p.V1460I | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs145799060, COSV62328823; called by muse, mutect2, varscan2
- VPS52 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV69385334; called by muse, mutect2, varscan2
- VTI1B | c.364A>G p.M122V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs377713040; called by muse, mutect2, varscan2
- WBP11 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs761866849, COSV53763829; called by muse, mutect2, varscan2
- WNT2B | c.539G>A p.R180H (on ENST00000369684 / NM_024494.3; = p.R161H on NM_004185.4) | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs35058556; called by muse, mutect2, varscan2
- XAB2 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs893224513, COSV50331839; called by muse, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs779864368; called by mutect2, varscan2
- XYLT2 | c.1790A>G p.Y597C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs762074183, COSV50019546; called by muse, mutect2, varscan2
- ZBTB39 | c.1798C>A p.P600T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55630021, COSV55631036; called by muse, mutect2, varscan2
- ZC3H13 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs374773951; called by muse, mutect2, varscan2
- ZFHX3 | c.10215del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs762108866; called by mutect2, pindel, varscan2
- ZMYM3 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV58739363; called by muse, mutect2, varscan2
- ZNF184 | c.164A>T p.D55V | Missense Mutation (SNP) | VAF 123/301 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV53004946; called by muse, mutect2, varscan2
- ZNF267 | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 119/248 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV56251339, COSV56254576; called by muse, mutect2, varscan2
- ZNF3 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV52796195; called by muse, mutect2, varscan2
- ZNF385A | c.244C>T p.R82C (on ENST00000338010 / NM_001130967.3; = p.R62C on NM_015481.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183182677, COSV61493212; called by muse, mutect2, varscan2
- ZNF43 | c.752del p.N251Ifs*28 | Frame Shift Del (DEL) | VAF 46/146 reads (32%) | catalogued as rs753886536; called by mutect2, varscan2
- ZNF521 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1256471171, COSV64126892, COSV64133323; called by muse, mutect2, varscan2
- ZNF583 | c.1481G>T p.C494F | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52403640, COSV99382269; called by muse, mutect2
- ZNF770 | c.584A>T p.K195I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62544619; called by muse, mutect2, varscan2
- ZSCAN1 | c.1148G>T p.S383I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as COSV56606519, COSV99991573; called by muse, mutect2, varscan2
- ZSCAN10 | c.223G>T p.G75W (on ENST00000252463; = p.G130W on NM_032805.3) | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52969353; called by muse, mutect2, varscan2
- ADRA1B | c.978del p.D327Tfs*88 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- AFF2 | c.1887del p.K629Nfs*126 | Frame Shift Del (DEL) | VAF 136/412 reads (33%) | called by mutect2, pindel, varscan2
- ANKRD13A | c.1120_1121del p.L374Gfs*9 | Frame Shift Del (DEL) | VAF 42/130 reads (32%) | called by pindel, varscan2
- ARHGAP5 | c.2805del p.F935Lfs*5 | Frame Shift Del (DEL) | VAF 98/256 reads (38%) | called by mutect2, pindel, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 40/127 reads (31%) | called by mutect2, pindel, varscan2
- ARNTL | c.994del p.E332Kfs*4 (on ENST00000403290 / NM_001297719.2; = p.E331Kfs*4 on NM_001178.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/109 reads (38%) | called by mutect2, pindel, varscan2
- ATM | c.4741del p.I1581Sfs*20 | Frame Shift Del (DEL) | VAF 83/232 reads (36%) | called by mutect2, pindel, varscan2
- CASD1 | c.1256del p.N419Ifs*8 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | called by mutect2, pindel, varscan2
- CCNG2 | c.725_727del p.F242del | In Frame Del (DEL) | VAF 54/143 reads (38%) | called by pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 64/177 reads (36%) | called by mutect2, pindel, varscan2
- CLSTN1 | c.173del p.P58Hfs*2 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- CNIH1 | c.394del p.Y132Tfs*6 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel
- CNTNAP5 | c.1153del p.Q385Kfs*7 | Frame Shift Del (DEL) | VAF 17/108 reads (16%) | called by mutect2, pindel, varscan2
- CRACD | c.501dup p.Q168Tfs*17 | Frame Shift Ins (INS) | VAF 36/98 reads (37%) | called by mutect2, varscan2
- CTCF | c.409dup p.A137Gfs*3 | Frame Shift Ins (INS) | VAF 54/164 reads (33%) | called by mutect2, varscan2
- DNAH17 | c.12390del p.N4131Tfs*34 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | called by mutect2, pindel
- DUXA | c.484del p.R162Gfs*7 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | called by mutect2, pindel, varscan2
- EAF2 | c.243del p.K81Nfs*4 | Frame Shift Del (DEL) | VAF 72/164 reads (44%) | called by mutect2, varscan2
- EZH1 | c.936del p.H313Mfs*55 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | called by mutect2, pindel, varscan2
- FILIP1L | c.1814del p.N605Tfs*3 (on ENST00000354552 / NM_182909.3; = p.N365Tfs*3 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 119/362 reads (33%) | called by mutect2, pindel, varscan2
- FRMD4B | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GAS2L2 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GFOD2 | c.701_702del p.C234* | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | called by pindel, varscan2
- GJA4 | c.954del p.K318Nfs*90 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- GPM6A | c.36del p.C14Vfs*17 | Frame Shift Del (DEL) | VAF 116/297 reads (39%) | called by mutect2, pindel, varscan2
- GUCY2C | c.2148del p.E717Sfs*2 | Frame Shift Del (DEL) | VAF 67/182 reads (37%) | called by mutect2, pindel, varscan2
- HDAC6 | c.2918del p.G973Efs*13 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- KCNB1 | c.2206del p.R736Gfs*9 | Frame Shift Del (DEL) | VAF 47/130 reads (36%) | called by mutect2, pindel, varscan2
- LAMA2 | c.7750del p.X2584_splice | Splice Site (DEL) | VAF 51/124 reads (41%) | called by mutect2, pindel, varscan2
- LIM2 | c.319del p.S107Pfs*43 (on ENST00000596399 / NM_001161748.2; = p.S149Pfs*43 on NM_030657.4) | Frame Shift Del (DEL) | VAF 27/70 reads (39%) | called by mutect2, pindel, varscan2
- MAGEF1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- MAST2 | c.2178del p.F726Lfs*12 | Frame Shift Del (DEL) | VAF 57/138 reads (41%) | called by mutect2, pindel, varscan2
- MASTL | c.1903del p.M635Cfs*2 | Frame Shift Del (DEL) | VAF 59/230 reads (26%) | called by mutect2, pindel, varscan2
- MYO9A | c.4264del p.Y1422Ifs*8 | Frame Shift Del (DEL) | VAF 57/150 reads (38%) | called by mutect2, varscan2
- NDC80 | c.1438del p.M480Wfs*7 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- NSD1 | c.5397del p.F1799Lfs*22 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- OR2F1 | c.898del p.A300Pfs*12 | Frame Shift Del (DEL) | VAF 71/258 reads (28%) | called by mutect2, pindel, varscan2
- PDS5B | c.2170del p.R724Vfs*32 | Frame Shift Del (DEL) | VAF 68/178 reads (38%) | called by mutect2, varscan2
- PHF20L1 | c.1602del p.V535* | Frame Shift Del (DEL) | VAF 68/144 reads (47%) | called by mutect2, varscan2
- PHF7 | c.1137del p.K379Nfs*7 | Frame Shift Del (DEL) | VAF 53/147 reads (36%) | called by mutect2, pindel, varscan2
- PIGB | c.529del p.C177Afs*26 | Frame Shift Del (DEL) | VAF 74/179 reads (41%) | called by mutect2, pindel, varscan2
- PLCZ1 | c.1589del p.N530Mfs*22 | Frame Shift Del (DEL) | VAF 56/140 reads (40%) | called by mutect2, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- POFUT2 | c.857del p.G286Afs*8 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- POLA1 | c.4266del p.F1422Lfs*28 | Frame Shift Del (DEL) | VAF 72/199 reads (36%) | called by mutect2, pindel, varscan2
- POM121C | c.2852C>G p.A951G (on ENST00000607367; = p.A709G on NM_001099415.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- PPT1 | c.166del p.M56Wfs*14 (on ENST00000433473; = p.M57Wfs*14 on NM_000310.4) | Frame Shift Del (DEL) | VAF 94/282 reads (33%) | called by mutect2, pindel, varscan2
- PRPF40A | c.1424del p.K475Sfs*40 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel
- R3HDM1 | c.2910del p.A971Lfs*26 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- RBM14 | c.1442_1484del p.G481Vfs*114 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | called by mutect2, pindel
- RFC3 | c.527_554del p.R176Lfs*21 | Frame Shift Del (DEL) | VAF 38/137 reads (28%) | called by mutect2, pindel, varscan2
- ROBO2 | c.3870del p.K1290Nfs*20 | Frame Shift Del (DEL) | VAF 66/194 reads (34%) | called by mutect2, pindel, varscan2
- RUNX1T1 | c.1212dup p.G405Rfs*5 (on ENST00000265814 / NM_001198628.1; = p.G378Rfs*5 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 34/120 reads (28%) | called by mutect2, varscan2
- SEMA4F | c.1828del p.R610Gfs*9 | Frame Shift Del (DEL) | VAF 54/153 reads (35%) | called by mutect2, pindel, varscan2
- SFSWAP | c.526_527del p.N176* | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- SLC14A2 | c.1654del p.R552Gfs*13 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | called by mutect2, pindel, varscan2
- SMYD3 | c.545_546del p.S182Ffs*5 (on ENST00000490107 / NM_001375962.1; = p.S123Ffs*5 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 44/184 reads (24%) | called by pindel, varscan2
- ST7L | c.1520del p.K507Rfs*19 | Frame Shift Del (DEL) | VAF 42/100 reads (42%) | called by mutect2, pindel, varscan2
- SUCNR1 | c.88del p.Y30Mfs*23 | Frame Shift Del (DEL) | VAF 126/357 reads (35%) | called by mutect2, pindel, varscan2
- TADA2A | c.668del p.I224Lfs*2 | Frame Shift Del (DEL) | VAF 35/82 reads (43%) | called by mutect2, pindel, varscan2
- TAF1L | c.1994del p.K665Rfs*4 | Frame Shift Del (DEL) | VAF 80/220 reads (36%) | called by mutect2, varscan2
- TCP1 | c.308del p.N103Mfs*5 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- TRIM26 | c.845dup p.T283Dfs*7 | Frame Shift Ins (INS) | VAF 48/110 reads (44%) | called by mutect2, varscan2
- USF3 | c.38del p.K13Sfs*26 | Frame Shift Del (DEL) | VAF 154/404 reads (38%) | called by mutect2, pindel, varscan2
- VCL | c.2196del p.D733Tfs*7 | Frame Shift Del (DEL) | VAF 29/109 reads (27%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.7668_7669del p.Q2557Efs*21 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | called by pindel, varscan2
- ZNF628 | c.2420del p.G807Vfs*9 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- ABCA13 | c.7323G>A p.L2441= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as rs755589892, COSV71291487; called by muse, mutect2, varscan2
- ACSM1 | c.352C>T p.L118= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV54638054; called by muse, mutect2
- APEX2 | c.267T>C p.N89= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV66624266; called by muse, mutect2, varscan2
- ATAD2 | c.585T>C p.R195= | Silent (SNP) | VAF 4/96 reads (4%) | catalogued as COSV54884040; called by muse, mutect2
- ATP6V1B1 | c.537C>T p.R179= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs545034098, COSV52268931; called by muse, mutect2, varscan2
- B4GALT6 | c.720C>T p.Y240= | Silent (SNP) | VAF 90/234 reads (38%) | catalogued as rs1217256257, COSV52704231, COSV52704340; called by muse, mutect2, varscan2
- BMP6 | c.1521A>G p.V507= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as rs1283820304, COSV51669337; called by muse, varscan2
- BRIP1 | c.798G>A p.T266= | Silent (SNP) | VAF 80/171 reads (47%) | catalogued as rs1260055674, COSV52004055; ClinVar: likely benign; called by muse, mutect2, varscan2
- BTBD2 | c.1206C>T p.F402= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs752556906, COSV55309722; called by muse, mutect2
- C7orf31 | c.1071A>G p.P357= | Silent (SNP) | VAF 105/213 reads (49%) | catalogued as rs773181573, COSV52218912; called by muse, mutect2, varscan2
- CCDC114 | c.1572G>A p.Q524= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV59557657; called by muse, mutect2, varscan2
- CCNE1 | c.534G>A p.A178= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs368794196; called by muse, mutect2, varscan2
- CDKL5 | c.951T>C p.H317= | Silent (SNP) | VAF 84/189 reads (44%) | catalogued as rs374371309, COSV66112320; called by muse, mutect2, varscan2
- CENPL | c.129T>C p.T43= | Silent (SNP) | VAF 157/748 reads (21%) | catalogued as COSV61892527; called by muse, mutect2, varscan2
- CERS1 | c.858G>A p.A286= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs766021529, COSV55929902; called by muse, mutect2, varscan2
- CHRNA3 | c.486C>T p.D162= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as rs200927324, COSV58776539; called by muse, mutect2, varscan2
- CHRNA9 | c.786A>G p.P262= | Silent (SNP) | VAF 246/620 reads (40%) | catalogued as COSV59575219; called by muse, mutect2, varscan2
- CLEC3B | c.270C>A p.T90= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV56110095; called by muse, mutect2, varscan2
- CLMP | c.969A>G p.A323= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV71650298; called by muse, mutect2, varscan2
- CLPTM1L | c.435C>T p.T145= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs566053718, COSV57991635; called by muse, mutect2, varscan2
- CNPPD1 | c.189C>T p.V63= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs1450767249, COSV56088198; called by muse, mutect2, varscan2
- CNTNAP3 | c.2598G>A p.Q866= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- CSMD1 | c.6423A>G p.P2141= (on ENST00000520002; = p.P2140= on NM_033225.6) | Silent (SNP) | VAF 57/115 reads (50%) | catalogued as COSV59351690; called by muse, mutect2
- CYLC1 | c.81A>G p.S27= | Silent (SNP) | VAF 55/118 reads (47%) | catalogued as rs1198740969, COSV61414064; called by muse, mutect2, varscan2
- D2HGDH | c.1080C>T p.H360= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs765266342, COSV58322340; called by muse, mutect2, varscan2
- DAGLB | c.651G>T p.T217= | Silent (SNP) | VAF 69/181 reads (38%) | catalogued as rs753919500, COSV51705661; called by muse, mutect2, varscan2
- DCAF4L2 | c.483G>A p.A161= | Silent (SNP) | VAF 59/149 reads (40%) | catalogued as rs1369010251, COSV60480151; called by muse, mutect2, varscan2
- DCLRE1B | c.453A>T p.P151= | Silent (SNP) | VAF 10/221 reads (5%) | catalogued as COSV56725939; called by muse, mutect2
- DDX60 | c.4776G>C p.L1592= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as rs143944090; called by muse, mutect2, varscan2
- DENND5A | c.1416G>A p.L472= | Silent (SNP) | VAF 120/268 reads (45%) | catalogued as COSV60236067; called by muse, mutect2, varscan2
- DLGAP2 | c.2421C>T p.S807= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs755621517, COSV70097775; called by muse, mutect2, varscan2
- DOCK1 | c.3984C>T p.I1328= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs779206732, COSV54739072; called by muse, mutect2, varscan2
- DSPP | c.600T>C p.I200= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV56813340; called by muse, mutect2, varscan2
- EDEM1 | c.1845G>A p.P615= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs753556015, COSV56582940; called by muse, mutect2, varscan2
- EGF | c.135A>G p.A45= | Silent (SNP) | VAF 26/250 reads (10%) | catalogued as COSV54481556; called by muse, mutect2
- EMCN | c.711C>T p.S237= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as rs765467506, COSV56458445; called by muse, mutect2, varscan2
- ENPEP | c.48G>A p.T16= | Silent (SNP) | VAF 61/163 reads (37%) | catalogued as rs1225718514, COSV54454125; called by muse, mutect2, varscan2
- EPHX2 | c.1254C>T p.S418= | Silent (SNP) | VAF 47/164 reads (29%) | catalogued as rs762283533, COSV66844025; called by muse, mutect2, varscan2
- ESX1 | c.210C>T p.D70= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as COSV65424813; called by muse, mutect2, varscan2
- ESYT3 | c.1917C>T p.D639= | Silent (SNP) | VAF 77/182 reads (42%) | catalogued as rs201862785; called by muse, mutect2, varscan2
- ETFA | c.657A>G p.V219= | Silent (SNP) | VAF 116/238 reads (49%) | catalogued as COSV51211347; called by muse, varscan2
- FAM135B | c.4104C>T p.H1368= | Silent (SNP) | VAF 69/199 reads (35%) | catalogued as rs367883703; called by muse, mutect2, varscan2
- FAM9A | c.114C>T p.F38= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs746088694, COSV66812901; called by muse, mutect2, varscan2
- FCRL6 | c.237C>T p.G79= | Silent (SNP) | VAF 62/206 reads (30%) | catalogued as COSV58941907; called by muse, mutect2, varscan2
- FH | c.501T>C p.G167= | Silent (SNP) | VAF 98/485 reads (20%) | catalogued as COSV63818585; called by muse, mutect2, varscan2
- FPR1 | c.942C>T p.H314= | Silent (SNP) | VAF 79/184 reads (43%) | catalogued as rs749154560, COSV59052930; called by muse, mutect2, varscan2
- GABBR1 | c.249C>T p.A83= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as COSV63543571; called by muse, mutect2, varscan2
- GARNL3 | c.2676G>A p.T892= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs776796001, COSV59226566, COSV59228490; called by muse, mutect2, varscan2
- GJA5 | c.327G>T p.R109= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as COSV54785289; called by muse, mutect2, varscan2
- GLI3 | c.4077G>A p.G1359= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV67891673; called by muse, mutect2, varscan2
- GPAT2 | c.2088G>A p.P696= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1164175531, COSV64003726; called by muse, mutect2, varscan2
- HERC1 | c.5340C>T p.N1780= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as rs374580110; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGF1R | c.3996G>T p.G1332= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV51322771; called by muse, mutect2, varscan2
- IL10 | c.72C>A p.T24= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV65594774; called by muse, mutect2, varscan2
- IQGAP2 | c.447T>C p.I149= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV57177321; called by muse, mutect2, varscan2
- JCAD | c.117A>G p.A39= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs968794505, COSV64760727; called by muse, mutect2, varscan2
- KCNJ10 | c.228A>G p.A76= | Silent (SNP) | VAF 105/350 reads (30%) | catalogued as rs1249044917, COSV63634366; called by muse, mutect2, varscan2
- KLF3 | c.265C>A p.R89= | Silent (SNP) | VAF 56/109 reads (51%) | catalogued as COSV54711694; called by muse, mutect2, varscan2
- KRT85 | c.204A>G p.V68= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV57737569; called by muse, mutect2, varscan2
- LATS1 | c.1155C>T p.S385= | Silent (SNP) | VAF 122/296 reads (41%) | catalogued as COSV53595424; called by muse, mutect2, varscan2
- LIMS1 | c.816C>T p.C272= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV57541162; called by muse, mutect2, varscan2
- LMAN2 | c.393C>T p.D131= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs369932800; called by muse, mutect2, varscan2
- MAOA | c.1326C>T p.S442= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs771100973, COSV58642225; called by muse, mutect2
- MAP2K4 | c.1092T>C p.H364= | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as COSV62259114; called by muse, mutect2, varscan2
- MC4R | c.690C>T p.P230= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as rs148026669; called by muse, mutect2, varscan2
- MCEMP1 | c.126C>A p.T42= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV58040482; called by muse, mutect2, varscan2
- MCF2L | c.843G>A p.A281= (on ENST00000375608; = p.A249= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs377408964; called by muse, mutect2
- MTCL1 | c.2571C>T p.G857= (on ENST00000306329 / NM_001378206.1; = p.G497= on NM_015210.4) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs778541654, COSV60406702; called by muse, mutect2
- MTHFS | c.564C>T p.N188= | Silent (SNP) | VAF 88/214 reads (41%) | catalogued as rs753238244, COSV51913990; called by muse, mutect2, varscan2
- MYOCD | c.492G>A p.P164= | Silent (SNP) | VAF 128/286 reads (45%) | catalogued as rs745617618, COSV58507592; called by muse, mutect2, varscan2
- NAE1 | c.768T>C p.N256= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs763831583, COSV51977268; called by muse, mutect2, varscan2
- NAP1L4 | c.984C>A p.V328= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV65881624; called by muse, mutect2, varscan2
- NKX6-1 | c.786G>A p.A262= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV55685265; called by muse, mutect2, varscan2
- NRXN2 | c.4137G>A p.R1379= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV55458576; called by muse, mutect2, varscan2
- NYAP2 | c.1437C>T p.P479= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs774130262, COSV56011187, COSV99796066; called by muse, mutect2, varscan2
- PACSIN2 | c.162G>A p.A54= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs201219931, COSV54321316, COSV99605943; called by muse, mutect2, varscan2
- PBLD | c.516G>A p.S172= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as rs375720476; called by muse, mutect2, varscan2
- PCDHA3 | c.2118G>A p.A706= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV63539926; called by muse, mutect2, varscan2
- PCSK5 | c.2904G>A p.E968= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV70449719; called by muse, mutect2, varscan2
- PITX1 | c.495C>T p.S165= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV54762610; called by muse, mutect2, varscan2
- PKDREJ | c.2514A>G p.S838= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV53550971; called by muse, mutect2, varscan2
- PLCG2 | c.1158G>A p.V386= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as rs774804571, COSV63872764; called by muse, mutect2
- PLCL1 | c.2514C>T p.H838= | Silent (SNP) | VAF 87/183 reads (48%) | catalogued as rs1273210081, COSV70826317, COSV70850397; called by muse, mutect2, varscan2
- PLXND1 | c.2374C>T p.L792= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1417436817, COSV60716410; called by muse, mutect2
- PNMA8B | c.1092C>T p.D364= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV66536961; called by muse, mutect2, varscan2
- POLR3A | c.3946C>T p.L1316= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs901741607, COSV64931528; called by muse, mutect2, varscan2
- PPM1F | c.75G>A p.T25= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs374314822; called by muse, mutect2, varscan2
- PPP1R3D | c.849G>A p.A283= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1402302860, COSV62564744; called by muse, mutect2
- PRKCE | c.687C>T p.P229= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs759793988, COSV60320481; called by muse, mutect2, varscan2
- PRPF6 | c.591T>C p.H197= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as COSV53874560; called by muse, mutect2, varscan2
- PRRC2C | c.8358A>G p.K2786= (on ENST00000367742; = p.K2784= on NM_015172.4) | Silent (SNP) | VAF 78/235 reads (33%) | catalogued as rs1467838061, COSV58904860, COSV58908745; called by muse, mutect2, varscan2
- PSMB10 | c.717C>T p.G239= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV52123757; called by muse, mutect2, varscan2
- RASSF5 | c.777G>A p.Q259= | Silent (SNP) | VAF 61/205 reads (30%) | catalogued as COSV58797488; called by muse, mutect2, varscan2
- RGS3 | c.2811G>A p.L937= (on ENST00000350696 / NM_001282923.2; = p.L656= on NM_130795.4) | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV59518974; called by muse, mutect2, varscan2
- RIPOR2 | c.333C>T p.R111= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV52425653; called by muse, mutect2, varscan2
- RNF113A | c.321A>G p.K107= | Silent (SNP) | VAF 100/228 reads (44%) | catalogued as COSV65097631; called by muse, mutect2, varscan2
- RTL8A | c.132C>T p.I44= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as rs1485901611, COSV66188725; called by muse, mutect2, varscan2
- RTN2 | c.399C>T p.S133= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs138223572, COSV55595174; called by muse, mutect2, varscan2
- SASH1 | c.3135A>G p.S1045= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV66563601; called by muse, mutect2, varscan2
- SCN10A | c.252G>A p.P84= | Silent (SNP) | VAF 225/575 reads (39%) | catalogued as rs1486528454, COSV71860779; called by muse, mutect2, varscan2
- SCN5A | c.1347C>A p.T449= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs45477694, COSV61132584; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINB9 | c.198T>C p.I66= | Silent (SNP) | VAF 9/250 reads (4%) | catalogued as rs1561646285, COSV66233916; called by muse, mutect2
- SLC13A1 | c.1078C>T p.L360= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as COSV52014229; called by muse, mutect2, varscan2
- SLC16A14 | c.471C>T p.R157= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs1309691111, COSV54619265; called by muse, mutect2, varscan2
- SLC16A2 | c.333C>T p.N111= | Silent (SNP) | VAF 2/10 reads (20%) | catalogued as COSV52086662; called by muse, mutect2
- SLC22A23 | c.1929G>A p.P643= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs777092248, COSV66678489; called by muse, mutect2, varscan2
- SLC2A7 | c.171C>T p.N57= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as rs746026037, COSV68902120; called by muse, mutect2, varscan2
- SLX4 | c.1320G>A p.A440= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs776448104, COSV53564972; called by muse, mutect2, varscan2
- SPAG5 | c.1062C>T p.V354= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV58803019; called by muse, mutect2, varscan2
- SPEG | c.2481C>T p.D827= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs563909411, COSV56674973; called by muse, mutect2, varscan2
- SRGAP1 | c.1371A>G p.Q457= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV61900713; called by muse, mutect2, varscan2
- STAT3 | c.984C>T p.C328= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV52890493; called by muse, mutect2, varscan2
- TAS1R2 | c.1686T>C p.H562= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV64746021; called by muse, mutect2, varscan2
- TAS2R8 | c.669A>G p.R223= | Silent (SNP) | VAF 67/157 reads (43%) | catalogued as COSV53689907; called by muse, mutect2, varscan2
- TBC1D24 | c.837G>A p.T279= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs368286737; called by muse, mutect2, varscan2
- THOC1 | c.1497A>G p.L499= | Silent (SNP) | VAF 98/229 reads (43%) | catalogued as rs1249746876, COSV55276402; called by muse, mutect2, varscan2
- THOC2 | c.4263C>A p.S1421= | Silent (SNP) | VAF 191/530 reads (36%) | catalogued as COSV55550928; called by muse, mutect2, varscan2
- TMCO3 | c.34C>T p.L12= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV60261952; called by muse, mutect2, varscan2
- TMEM200A | c.768C>T p.G256= | Silent (SNP) | VAF 106/265 reads (40%) | catalogued as COSV51653774; called by muse, mutect2, varscan2
- TRIM9 | c.582C>T p.R194= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV53621206; called by muse, mutect2, varscan2
- TRMT10C | c.117C>T p.Y39= | Silent (SNP) | VAF 136/293 reads (46%) | catalogued as COSV59306335; called by muse, mutect2, varscan2
- TSBP1 | c.1350A>G p.E450= (on ENST00000617061; = p.E455= on NM_006781.5) | Silent (SNP) | VAF 210/613 reads (34%) | catalogued as COSV66660092; called by muse, mutect2, varscan2
- TSC22D1 | c.1503G>A p.Q501= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs767989400, COSV71775449; called by muse, mutect2, varscan2
- TYK2 | c.756G>A p.Q252= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1008962904, COSV53389524; called by muse, mutect2, varscan2
- UBN1 | c.87T>C p.A29= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV52170356; called by muse, mutect2, varscan2
- USP16 | c.153T>C p.C51= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV57626752; called by muse, mutect2, varscan2
- WWC1 | c.2097C>T p.R699= | Silent (SNP) | VAF 72/148 reads (49%) | catalogued as rs374509968; called by muse, mutect2, varscan2
- ZBTB41 | c.1932T>C p.D644= | Silent (SNP) | VAF 10/226 reads (4%) | catalogued as COSV66359518; called by muse, mutect2
- ZMYND11 | c.1776G>A p.A592= | Silent (SNP) | VAF 74/261 reads (28%) | catalogued as rs770351439, COSV59080156; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF20 | c.264G>A p.Q88= | Silent (SNP) | VAF 129/297 reads (43%) | catalogued as COSV62000003; called by muse, mutect2, varscan2
- ZNF432 | c.585T>C p.H195= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV55417629; called by muse, mutect2
- ZNF563 | c.114G>A p.R38= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV53371362; called by muse, mutect2, varscan2
- ZNF638 | c.3651T>C p.I1217= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV52491790; called by muse, mutect2, varscan2
- AC073310.1 | n.207T>C | RNA (SNP) | VAF 85/239 reads (36%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823313 T>C | 5'Flank (SNP) | VAF 16/42 reads (38%) | catalogued as rs1422212601; called by mutect2, varscan2
- DCHS2 | n.4400A>G | RNA (SNP) | VAF 112/268 reads (42%) | catalogued as COSV61775961; called by muse, mutect2, varscan2
- GLG1 | c.*1063T>C | 3'UTR (SNP) | VAF 17/41 reads (41%) | catalogued as COSV52670819; called by muse, mutect2, varscan2
- GLOD4 | chr17:783264 A>G | 5'Flank (SNP) | VAF 16/49 reads (33%) | catalogued as rs758011689, COSV56754484; called by muse, varscan2
- MARCHF1 | c.-322-85693C>T | Intron (SNP) | VAF 77/185 reads (42%) | catalogued as COSV72276311; called by muse, mutect2, varscan2
- OR2W5 | n.940G>A | RNA (SNP) | VAF 63/248 reads (25%) | catalogued as rs539711132; called by muse, mutect2, varscan2
